Somatic mutation profile of tumor specimen ecf1ca92-c8b7-470f-baf4-81cf73 (aliquot ecf1ca92-c8b7-470f-baf4-81cf73_D6_2) from CPTAC case 11CO053, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA.
Specimen ecf1ca92-c8b7-470f-baf4-81cf73: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c495d773-73a6-4f64-aedb-ddf88af95e7c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 5bf39865-182c-4c82-90e4-a7ea59 (Blood Derived Normal), aliquot 5bf39865-182c-4c82-90e4-a7ea59_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64703feb-6ccf-44e3-a123-97361d029af2

The open-access MAF lists 318 somatic variants for this specimen: 216 protein-altering or splice-affecting, 57 silent, 45 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 197, Silent 57, Intron 22, RNA 10, 3'UTR 9, Frame Shift Ins 5, Splice Site 5, Nonsense Mutation 4, 5'UTR 2, Frame Shift Del 2, Splice Region 2, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3956del p.P1319Lfs*2 | Frame Shift Del (DEL) | VAF 158/364 reads (43%) | catalogued as rs1057517558, COSV57356047, COSV57400437; ClinVar: pathogenic; called by mutect2, varscan2
- CD40LG | c.686T>C p.F229S | Missense Mutation (SNP) | VAF 7/203 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1569377865; ClinVar: likely pathogenic; called by muse, mutect2
- RRM2B | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 92/669 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.201); catalogued as rs776184830; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 290/540 reads (54%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.467); catalogued as rs876660825, CM161004, COSV52664064, COSV52987047, COSV53313892; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACP6 | c.766G>A p.V256M | Missense Mutation (SNP) | VAF 40/74 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.059); catalogued as rs782552755; called by muse, mutect2, varscan2
- ACTR3C | c.421G>C p.D141H | Missense Mutation (SNP) | VAF 12/272 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99336518; called by muse, mutect2
- ADAMTS17 | c.3121C>T p.R1041C | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs149434438; called by muse, mutect2, varscan2
- ADAMTS8 | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 165/373 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as rs766832143, COSV57292764; called by muse, mutect2, varscan2
- AKR1D1 | c.22C>A p.H8N | Missense Mutation (SNP) | VAF 27/187 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); catalogued as COSV99652998; called by muse, mutect2, varscan2
- ALDH1L1 | c.1306G>A p.A436T | Missense Mutation (SNP) | VAF 94/158 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs9282692, COSV56418272; called by muse, mutect2, varscan2
- ANKRD2 | c.398C>T p.S133L | Missense Mutation (SNP) | VAF 38/251 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs776638651; called by muse, mutect2, varscan2
- ANKRD26 | c.3896C>T p.A1299V | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.124); catalogued as rs1429452589; called by muse, mutect2, varscan2
- AP5S1 | c.196C>T p.R66W | Missense Mutation (SNP) | VAF 53/219 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs367607495; called by muse, mutect2, varscan2
- APOB | c.3004G>C p.E1002Q | Missense Mutation (SNP) | VAF 36/387 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.944); catalogued as COSV99267223; called by muse, mutect2
- ARHGAP6 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.043); catalogued as rs1035029406; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 58/237 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.025); catalogued as rs149330911, COSV63437569; called by muse, mutect2, varscan2
- ATP1A1 | c.1030C>G p.L344V | Missense Mutation (SNP) | VAF 38/200 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55193396; called by muse, mutect2, varscan2
- ATP8B1 | c.1718C>A p.T573N | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52178772; called by muse, mutect2, varscan2
- BBX | c.1969G>T p.E657* | Nonsense Mutation (SNP) | VAF 12/87 reads (14%) | catalogued as COSV57896317; called by muse, mutect2, varscan2
- CASZ1 | c.1841G>A p.R614H | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs777873291, COSV59739865; called by muse, mutect2, varscan2
- CCDC184 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 146/309 reads (47%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs1249124082; called by muse, mutect2, varscan2
- CDC25B | c.987C>G p.I329M (on ENST00000245960 / NM_021873.3; = p.I315M on NM_004358.4) | Missense Mutation (SNP) | VAF 65/230 reads (28%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as rs1219380120; called by muse, mutect2, varscan2
- CFAP61 | c.1858C>G p.P620A | Missense Mutation (SNP) | VAF 35/202 reads (17%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.999); catalogued as COSV55640141; called by muse, mutect2, varscan2
- CLPS | c.209C>T p.T70M | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs140627661; called by muse, mutect2
- CLSTN2 | c.1078G>A p.G360S | Missense Mutation (SNP) | VAF 325/529 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs771528135, COSV101515851; called by mutect2, varscan2
- CSMD3 | c.4932C>G p.I1644M (on ENST00000297405 / NM_001363185.1; = p.I1540M on NM_052900.3) | Missense Mutation (SNP) | VAF 13/210 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV99841324; called by muse, mutect2
- CYP2A13 | c.346G>A p.V116M | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as rs751293256, COSV57838095; called by muse, mutect2, varscan2
- DNAH5 | c.3655C>T p.R1219C | Missense Mutation (SNP) | VAF 43/173 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.489); catalogued as rs745321705, COSV54204972; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DPP6 | c.2573C>T p.A858V (on ENST00000377770 / NM_001364500.2; = p.A796V on NM_001936.5) | Missense Mutation (SNP) | VAF 52/195 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.024); catalogued as rs781585134, COSV59616168; called by muse, mutect2, varscan2
- DRAP1 | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1482220567; called by muse, mutect2, varscan2
- DUSP5 | c.853C>T p.R285C | Missense Mutation (SNP) | VAF 56/209 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1026457804, COSV63645340; called by muse, mutect2, varscan2
- EFS | c.1244C>T p.A415V | Missense Mutation (SNP) | VAF 56/125 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.168); catalogued as rs373976977, COSV53734153; called by muse, mutect2, varscan2
- EYS | c.2546G>A p.R849H | Missense Mutation (SNP) | VAF 49/145 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs775080539; called by muse, mutect2, varscan2
- GCC2 | c.1048A>C p.I350L | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as rs767153817; called by muse, mutect2, varscan2
- GRAMD1B | c.1031A>G p.D344G | Missense Mutation (SNP) | VAF 18/248 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.444); catalogued as COSV59202183; called by muse, mutect2
- HAPLN3 | c.290C>G p.P97R | Missense Mutation (SNP) | VAF 44/179 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV100613665; called by muse, mutect2, varscan2
- HMCN1 | c.10502C>T p.S3501L | Missense Mutation (SNP) | VAF 71/269 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.183); catalogued as rs1378615482, COSV54936184; called by muse, mutect2, varscan2
- IFI44L | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs974783332, COSV60728784; called by muse, mutect2, varscan2
- IGHD3-9 | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 80/239 reads (33%) | catalogued as rs782434392; called by muse, mutect2, varscan2
- IGSF3 | c.1285C>T p.R429C (on ENST00000369486 / NM_001007237.3; = p.R449C on NM_001542.4) | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); catalogued as rs968366784, COSV59586064; called by muse, mutect2, varscan2
- INHBB | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated (0.47); PolyPhen benign (0.022); catalogued as rs756593615; called by muse, mutect2, varscan2
- JAK1 | c.1360C>T p.R454W | Missense Mutation (SNP) | VAF 87/199 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs1240783724, COSV61097942; called by muse, mutect2, varscan2
- KANK1 | c.870G>T p.K290N | Missense Mutation (SNP) | VAF 52/283 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1265416649; called by muse, mutect2, varscan2
- KATNAL2 | c.490G>A p.G164S (on ENST00000356157 / NM_001353899.1; = p.G92S on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/76 reads (59%) | SIFT tolerated (0.11); PolyPhen benign (0.3); catalogued as rs748167860; called by muse, mutect2, varscan2
- KIF26B | c.4205G>A p.R1402Q | Missense Mutation (SNP) | VAF 113/262 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.09); catalogued as rs200347978, COSV63643833; called by muse, mutect2, varscan2
- KL | c.1599+6T>C | Splice Region (SNP) | VAF 124/421 reads (29%) | catalogued as rs1162636278; called by muse, mutect2, varscan2
- KMT2C | c.1320G>C p.E440D | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.34); catalogued as rs1320493341; called by muse, mutect2, varscan2
- LMF2 | c.1733G>A p.R578H | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs749758476, COSV53319407; called by muse, mutect2, varscan2
- LRRFIP1 | c.1804T>A p.L602I (on ENST00000392000 / NM_001137552.2; = p.L578I on NM_004735.4) | Missense Mutation (SNP) | VAF 42/197 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV99790510; called by muse, mutect2, varscan2
- LRRK2 | c.4613G>T p.R1538L | Missense Mutation (SNP) | VAF 13/223 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); catalogued as rs200631999, COSV54161630; called by muse, mutect2
- LSR | c.1454G>A p.R485Q (on ENST00000361790; = p.R466Q on NM_015925.6) | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.019); catalogued as rs1039343195; called by muse, mutect2
- LVRN | c.1885G>C p.D629H | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV63497473; called by muse, mutect2, varscan2
- MAST2 | c.3455G>A p.R1152H | Missense Mutation (SNP) | VAF 54/229 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.98); catalogued as rs750515082; called by muse, mutect2, varscan2
- MATN4 | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 17/305 reads (6%) | PolyPhen benign (0.001); catalogued as COSV59213417; called by muse, mutect2
- MEIOC | c.1651A>G p.S551G | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1360307860; called by muse, mutect2, varscan2
- METTL1 | c.652G>C p.E218Q | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.378); catalogued as rs372333605; called by muse, mutect2, varscan2
- MYH7 | c.3524G>A p.R1175Q | Missense Mutation (SNP) | VAF 102/474 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); catalogued as rs776802481; called by muse, mutect2, varscan2
- MYO16 | c.3334C>T p.R1112* | Nonsense Mutation (SNP) | VAF 9/165 reads (5%) | catalogued as COSV62747681; called by muse, mutect2
- NUP54 | c.908-1G>C p.X303_splice | Splice Site (SNP) | VAF 11/64 reads (17%) | catalogued as COSV53576177; called by muse, mutect2, varscan2
- NUTM2G | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 81/348 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs541253499, COSV63616879; called by muse, mutect2, varscan2
- OR12D2 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); catalogued as rs1458564754, COSV65826259; called by muse, mutect2, varscan2
- OR51S1 | c.468T>G p.I156M | Missense Mutation (SNP) | VAF 26/235 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); catalogued as COSV59057891; called by muse, mutect2, varscan2
- OR56A4 | c.610A>G p.I204V | Missense Mutation (SNP) | VAF 12/292 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1353450553; called by muse, mutect2
- P2RX7 | c.1423G>A p.V475I | Missense Mutation (SNP) | VAF 46/175 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.056); catalogued as rs367838751, COSV55857014; called by muse, mutect2, varscan2
- PIK3C2G | c.2516dup p.N839Kfs*5 (on ENST00000676171; = p.N798Kfs*5 on NM_004570.5) | Frame Shift Ins (INS) | VAF 8/36 reads (22%) | catalogued as rs1229278001; called by mutect2, pindel, varscan2
- PPFIA4 | c.1526C>T p.S509L (on ENST00000447715; = p.S484L on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as rs780895208; called by muse, mutect2, varscan2
- PRL | c.204C>T p.F68= | Splice Region (SNP) | VAF 84/141 reads (60%) | catalogued as rs1328141274, COSV60591377; called by muse, mutect2, varscan2
- PTPRG | c.4177G>T p.V1393L | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.422); catalogued as COSV55655529; called by muse, mutect2, varscan2
- RBPJ | c.73C>T p.R25W | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs1476504593, COSV100623470; called by muse, mutect2, varscan2
- RIMS2 | c.1342T>G p.L448V (on ENST00000666250 / NM_001348490.2; = p.L256V on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/326 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.034); catalogued as COSV51669105, COSV51676746; called by muse, mutect2
- SASS6 | c.155C>T p.T52M | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); catalogued as rs572173728, COSV54927070; called by muse, mutect2, varscan2
- SCAI | c.203A>T p.K68I (on ENST00000336505 / NM_001144877.3; = p.K91I on NM_173690.5) | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs983093168, COSV60612530; called by muse, mutect2, varscan2
- SEC14L3 | c.989C>T p.S330L | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1299842324, COSV68844280; called by muse, mutect2, varscan2
- SLC5A7 | c.463G>A p.V155M | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs775903161, COSV99886443; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPG11 | c.5599G>A p.E1867K | Missense Mutation (SNP) | VAF 107/391 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs372419484; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPTBN4 | c.6871C>T p.R2291W | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.824); catalogued as COSV100150698; called by muse, mutect2, varscan2
- STAT5B | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 75/158 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV53186890; called by muse, mutect2, varscan2
- SULF2 | c.2422G>A p.V808I | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs551763867; called by muse, mutect2, varscan2
- SUPT20H | c.588G>C p.E196D (on ENST00000350612 / NM_001014286.3; = p.E197D on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1321196072; called by muse, mutect2, varscan2
- SWT1 | c.184G>A p.V62I | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757367594, COSV62259465; called by muse, mutect2, varscan2
- TAS2R39 | c.971G>A p.R324Q | Missense Mutation (SNP) | VAF 30/232 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs755602052, COSV101489412; called by muse, mutect2, varscan2
- TOB2 | c.919G>A p.G307S | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.048); catalogued as rs1569268816; called by muse, mutect2, varscan2
- TRGV1 | c.278G>A p.S93N | Missense Mutation (SNP) | VAF 43/146 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs995833933; called by muse, mutect2, varscan2
- TTN | c.74328G>C p.E24776D (on ENST00000591111; = p.E17352D on NM_003319.4) | Missense Mutation (SNP) | VAF 50/566 reads (9%) | PolyPhen benign (0.009); catalogued as rs369019463; ClinVar: uncertain significance; called by muse, mutect2
- TTN | c.27595C>T p.R9199C (on ENST00000591111; = p.R8272C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/269 reads (22%) | PolyPhen probably damaging (0.982); catalogued as rs751958797, COSV100638442; called by muse, mutect2, varscan2
- TTN | c.16241C>G p.S5414C (on ENST00000591111; = p.S4487C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/125 reads (6%) | PolyPhen benign (0.298); catalogued as COSV59986352; called by muse, mutect2
- UHRF1BP1L | c.1576C>A p.L526M | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.844); catalogued as rs1426381386; called by muse, mutect2, varscan2
- UPF3B | c.763A>G p.R255G | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.452); catalogued as rs985384811; called by muse, mutect2, varscan2
- USP29 | c.2530G>A p.D844N | Missense Mutation (SNP) | VAF 79/193 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs1262776912, COSV54142444; called by muse, mutect2, varscan2
- WDR24 | c.1951A>G p.I651V (on ENST00000248142; = p.I521V on NM_032259.4) | Missense Mutation (SNP) | VAF 34/234 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as rs1162654051; called by muse, mutect2, varscan2
- ZNF671 | c.1603del p.*535Kfs*23 | Frame Shift Del (DEL) | VAF 23/126 reads (18%) | catalogued as COSV58052913; called by mutect2, pindel, varscan2
- ZSWIM2 | c.1668G>C p.K556N | Missense Mutation (SNP) | VAF 74/290 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as COSV54575019; called by muse, mutect2, varscan2
- ADAMTS20 | c.1937G>C p.S646T | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- ADGRG4 | c.419A>G p.E140G | Missense Mutation (SNP) | VAF 91/381 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- ADGRG4 | c.3001G>A p.A1001T | Missense Mutation (SNP) | VAF 31/194 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- AFG3L2 | c.340G>T p.G114C | Missense Mutation (SNP) | VAF 85/319 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- AP000812.4 | c.665T>A p.L222Q | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- APC | c.732_736dup p.S246Cfs*49 | Frame Shift Ins (INS) | VAF 28/96 reads (29%) | called by mutect2, pindel, varscan2
- BCAS3 | c.2336_2337insG p.D779Efs*3 (on ENST00000390652 / NM_001353144.2; = p.D764Efs*3 on NM_017679.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 39/182 reads (21%) | called by mutect2, pindel, varscan2
- C2CD4C | c.35T>G p.L12R | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- CACNB4 | c.1038T>G p.I346M | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- CCDC120 | c.1693C>T p.R565W | Missense Mutation (SNP) | VAF 41/206 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CCDC178 | c.379A>T p.T127S | Missense Mutation (SNP) | VAF 6/101 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.015); called by muse, mutect2
- CCL1 | c.265A>G p.R89G | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, varscan2
- CCNG1 | c.805G>A p.V269I | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CCZ1B | c.1266-1G>A p.X422_splice | Splice Site (SNP) | VAF 24/97 reads (25%) | called by muse, mutect2, varscan2
- CD163 | c.934G>T p.A312S | Missense Mutation (SNP) | VAF 35/215 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.336); called by mutect2, varscan2
- CDH2 | c.1622C>A p.A541D | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- CEP135 | c.3197C>A p.T1066N | Missense Mutation (SNP) | VAF 44/175 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CEP170 | c.3326G>A p.G1109D | Missense Mutation (SNP) | VAF 45/296 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CFAP221 | c.307G>C p.E103Q | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNBD1 | c.131C>A p.A44E | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.923); called by muse, mutect2
- DENND4A | c.3880G>T p.E1294* | Nonsense Mutation (SNP) | VAF 42/135 reads (31%) | called by muse, mutect2, varscan2
- DISP1 | c.2885T>C p.L962P | Missense Mutation (SNP) | VAF 18/562 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DMRT1 | c.670A>T p.N224Y | Missense Mutation (SNP) | VAF 93/387 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- DNAJC13 | c.2092C>T p.P698S | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- DNAJC2 | c.1415G>T p.G472V | Missense Mutation (SNP) | VAF 58/192 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- DNTT | c.767T>G p.F256C | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DNTT | c.769G>A p.G257R | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- DST | c.12689C>G p.P4230R (on ENST00000361203 / NM_001374722.1; = p.P1818R on NM_015548.5) | Missense Mutation (SNP) | VAF 86/157 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- DTWD2 | c.884G>A p.S295N | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DYNC1H1 | c.6728G>C p.R2243T | Missense Mutation (SNP) | VAF 53/235 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ECM2 | c.1853A>G p.N618S | Missense Mutation (SNP) | VAF 36/175 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ELOA | c.1865A>G p.N622S | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ENDOV | c.608G>T p.S203I | Missense Mutation (SNP) | VAF 47/206 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- ERICH3 | c.2975C>A p.T992K | Missense Mutation (SNP) | VAF 48/243 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- FAM126B | c.109C>G p.L37V | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FBN2 | c.3344-1G>C p.X1115_splice | Splice Site (SNP) | VAF 79/453 reads (17%) | called by muse, mutect2, varscan2
- FREM2 | c.929G>C p.R310P | Missense Mutation (SNP) | VAF 17/319 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); called by muse, mutect2
- FSIP2 | c.19514A>C p.Q6505P | Missense Mutation (SNP) | VAF 40/213 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- G6PD | c.136A>G p.K46E | Missense Mutation (SNP) | VAF 50/295 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- GALNTL5 | c.431A>G p.N144S | Missense Mutation (SNP) | VAF 13/386 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GLT8D2 | c.285-12_290del p.X95_splice | Splice Site (DEL) | VAF 18/118 reads (15%) | called by mutect2, pindel, varscan2
- GNS | c.245C>A p.S82Y | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- GOLGA6L6 | c.1044G>C p.E348D | Missense Mutation (SNP) | VAF 34/298 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, varscan2
- GPR148 | c.167C>G p.S56* | Nonsense Mutation (SNP) | VAF 78/338 reads (23%) | called by muse, mutect2, varscan2
- GYS2 | c.1783C>G p.L595V | Missense Mutation (SNP) | VAF 126/303 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- HACE1 | c.2442G>C p.Q814H | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2
- HDGFL3 | c.208G>C p.D70H | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- HEATR5B | c.3410G>C p.C1137S | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- HECTD4 | c.4243-1G>C p.X1415_splice | Splice Site (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- HNF4G | c.187C>A p.Q63K (on ENST00000354370 / NM_001330561.2; = p.Q110K on NM_004133.5) | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- IFT80 | c.2313G>C p.K771N | Missense Mutation (SNP) | VAF 11/184 reads (6%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); called by muse, mutect2
- IFT88 | c.1511T>A p.F504Y (on ENST00000319980 / NM_001318493.2; = p.F495Y on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- KANSL1 | c.3129C>G p.H1043Q (on ENST00000574590 / NM_001193465.2; = p.H1044Q on NM_015443.4) | Missense Mutation (SNP) | VAF 44/179 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- KLK2 | c.487G>C p.E163Q | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KYNU | c.1039G>C p.E347Q | Missense Mutation (SNP) | VAF 44/228 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- LAMA3 | c.7589A>G p.N2530S (on ENST00000313654 / NM_198129.4; = p.N921S on NM_000227.6) | Missense Mutation (SNP) | VAF 73/279 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- LIG4 | c.2597G>T p.G866V | Missense Mutation (SNP) | VAF 24/280 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.416); called by muse, mutect2
- LRP12 | c.2137A>T p.S713C | Missense Mutation (SNP) | VAF 52/381 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- MACF1 | c.22094A>C p.K7365T (on ENST00000372915; = p.K5410T on NM_012090.5) | Missense Mutation (SNP) | VAF 25/112 reads (22%) | called by muse, mutect2, varscan2
- MARCHF3 | c.599C>A p.T200K | Missense Mutation (SNP) | VAF 40/250 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- MCOLN2 | c.204G>T p.L68F | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- MEOX2 | c.867T>A p.N289K | Missense Mutation (SNP) | VAF 220/501 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- MGAM2 | c.6649A>G p.I2217V | Missense Mutation (SNP) | VAF 44/676 reads (7%) | SIFT tolerated, low confidence (1); called by muse, mutect2
- MOS | c.166G>C p.D56H | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- MPHOSPH9 | c.298T>A p.C100S | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- MTREX | c.34G>C p.V12L | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- NLGN1 | c.1116G>T p.L372F | Missense Mutation (SNP) | VAF 28/244 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NPIPB4 | c.1957_1959del p.I653del | In Frame Del (DEL) | VAF 63/293 reads (22%) | called by pindel, varscan2
- NR0B1 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 45/271 reads (17%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OR14A2 | c.364G>A p.V122I | Missense Mutation (SNP) | VAF 40/223 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.047); called by muse, varscan2
- OR4Q2 | c.809C>A p.S270Y | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- OTUD4 | c.638C>A p.T213N (on ENST00000447906 / NM_001366057.1; = p.T148N on NM_001102653.1) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- PAPPA2 | c.2656G>C p.E886Q | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- PAPSS1 | c.280G>C p.G94R | Missense Mutation (SNP) | VAF 32/352 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHB16 | c.746T>A p.V249E | Missense Mutation (SNP) | VAF 86/390 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.869); called by mutect2, varscan2
- PCDHB5 | c.1889G>A p.S630N | Missense Mutation (SNP) | VAF 91/395 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- PDE1B | c.350A>C p.E117A | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- PDILT | c.825G>T p.M275I | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2
- PHF3 | c.2904_2905insG p.F969Vfs*8 | Frame Shift Ins (INS) | VAF 16/127 reads (13%) | called by mutect2, pindel, varscan2
- PKD2L1 | c.1279G>A p.D427N | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- PLA1A | c.217C>A p.L73I | Missense Mutation (SNP) | VAF 30/289 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PLXNA2 | c.5444A>G p.Y1815C | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PON3 | c.452C>G p.S151C | Missense Mutation (SNP) | VAF 24/452 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2
- POSTN | c.1818A>C p.E606D | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PPP4R3C | c.749A>C p.E250A | Missense Mutation (SNP) | VAF 72/306 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PRELID3A | c.341C>G p.P114R | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- PRRC2C | c.3196C>G p.P1066A (on ENST00000367742; = p.P1064A on NM_015172.4) | Missense Mutation (SNP) | VAF 57/128 reads (45%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PTPRQ | c.2371T>A p.L791I (on ENST00000616559; = p.L749I on NM_001145026.2) | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PTPRZ1 | c.1385C>G p.S462C | Missense Mutation (SNP) | VAF 31/226 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- RALA | c.127T>C p.Y43H | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RICTOR | c.2050T>C p.C684R | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.06); called by muse, mutect2
- RYR2 | c.12461A>T p.E4154V | Missense Mutation (SNP) | VAF 15/278 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2
- SDR16C5 | c.835A>C p.S279R | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.442); called by muse, mutect2, varscan2
- SHOX | c.44A>C p.K15T | Missense Mutation (SNP) | VAF 45/216 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SLC9C1 | c.1255T>A p.L419M | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SLCO1C1 | c.201C>G p.I67M | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2
- SLFN11 | c.2494A>C p.K832Q | Missense Mutation (SNP) | VAF 69/313 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- SPECC1 | c.1293G>C p.E431D | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0.029); called by muse, mutect2
- SPICE1 | c.2345A>C p.E782A | Missense Mutation (SNP) | VAF 33/50 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2384G>C p.R795T | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- SUPT20HL1 | c.1750C>A p.P584T | Missense Mutation (SNP) | VAF 21/402 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, mutect2
- TAF6L | c.1197C>G p.S399R | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.015); called by mutect2, varscan2
- TDRD6 | c.5769G>T p.L1923F | Missense Mutation (SNP) | VAF 51/294 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TERF1 | c.743T>G p.L248R | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TMTC1 | c.1867G>T p.G623W (on ENST00000539277 / NM_001193451.2; = p.G515W on NM_175861.3) | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, varscan2
- TRAK2 | c.2404_2405insG p.F802Cfs*8 | Frame Shift Ins (INS) | VAF 104/396 reads (26%) | called by mutect2, varscan2
- TRANK1 | c.6985G>A p.G2329S | Missense Mutation (SNP) | VAF 65/317 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TTN | c.97153A>C p.N32385H (on ENST00000591111; = p.N24961H on NM_003319.4) | Missense Mutation (SNP) | VAF 34/530 reads (6%) | PolyPhen probably damaging (0.974); called by muse, mutect2
- UBE4A | c.2305G>A p.A769T (on ENST00000252108 / NM_001204077.2; = p.A776T on NM_004788.4) | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- UMODL1 | c.2321G>T p.C774F (on ENST00000408910 / NM_001004416.2; = p.C902F on NM_173568.3) | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- UNC5A | c.1774C>T p.R592C | Missense Mutation (SNP) | VAF 54/364 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UNC80 | c.2560T>C p.S854P | Missense Mutation (SNP) | VAF 40/233 reads (17%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- USB1 | c.538G>T p.A180S | Missense Mutation (SNP) | VAF 91/463 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- UTP20 | c.670G>C p.V224L | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- VAX2 | c.539C>A p.S180Y | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- VNN1 | c.506A>T p.Q169L | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- VPS13B | c.3443A>G p.E1148G | Missense Mutation (SNP) | VAF 12/246 reads (5%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); called by muse, mutect2
- VPS26A | c.747G>C p.R249S | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- WLS | c.1505A>T p.D502V | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- ZBTB43 | c.216G>C p.L72F | Missense Mutation (SNP) | VAF 52/231 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ZNF292 | c.3778G>C p.D1260H | Missense Mutation (SNP) | VAF 59/264 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF567 | c.1589A>G p.E530G (on ENST00000536254 / NM_001322913.1; = p.E499G on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/179 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- ZNF790 | c.337G>C p.D113H | Missense Mutation (SNP) | VAF 36/193 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ZNF804B | c.3114G>C p.Q1038H | Missense Mutation (SNP) | VAF 26/452 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2
- ADRM1 | c.42C>T p.G14= | Silent (SNP) | VAF 16/171 reads (9%) | catalogued as rs984961806; called by muse, mutect2
- ARHGAP4 | c.966C>T p.L322= | Silent (SNP) | VAF 12/249 reads (5%) | catalogued as rs1417711316, COSV104415242; called by muse, mutect2
- ARHGEF5 | c.1272T>C p.G424= | Silent (SNP) | VAF 158/770 reads (21%) | called by mutect2, varscan2
- BICRA | c.780C>T p.S260= | Silent (SNP) | VAF 13/32 reads (41%) | called by muse, mutect2, varscan2
- C4orf54 | c.2706T>G p.T902= | Silent (SNP) | VAF 84/415 reads (20%) | called by muse, mutect2, varscan2
- C6orf132 | c.1323C>T p.L441= | Silent (SNP) | VAF 133/346 reads (38%) | catalogued as rs778068506; called by muse, mutect2, varscan2
- CASD1 | c.2079T>C p.R693= | Silent (SNP) | VAF 31/209 reads (15%) | called by muse, mutect2, varscan2
- CLCA4 | c.564C>T p.S188= | Silent (SNP) | VAF 22/95 reads (23%) | catalogued as rs202050195, COSV99760181; called by muse, mutect2, varscan2
- CLSTN1 | c.1581C>T p.G527= (on ENST00000377298 / NM_001009566.3; = p.G517= on NM_014944.4) | Silent (SNP) | VAF 26/111 reads (23%) | catalogued as rs564728676; called by muse, mutect2, varscan2
- CNTN2 | c.1545C>T p.P515= | Silent (SNP) | VAF 17/101 reads (17%) | catalogued as rs200105942; called by muse, mutect2, varscan2
- DLG5 | c.1662G>A p.A554= | Silent (SNP) | VAF 37/95 reads (39%) | catalogued as rs150912032; called by muse, mutect2, varscan2
- DNTTIP2 | c.27T>G p.A9= | Silent (SNP) | VAF 23/157 reads (15%) | called by muse, mutect2, varscan2
- DUSP6 | c.783G>A p.S261= | Silent (SNP) | VAF 82/211 reads (39%) | catalogued as rs779747736; called by muse, mutect2, varscan2
- FAM47A | c.711G>A p.P237= | Silent (SNP) | VAF 53/223 reads (24%) | catalogued as rs780490487, COSV100649762; called by mutect2, varscan2
- FLG2 | c.6423C>T p.H2141= | Silent (SNP) | VAF 216/498 reads (43%) | catalogued as rs748200639, COSV66169820; called by mutect2, varscan2
- FOXL3 | c.513C>T p.G171= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as COSV101546366; called by muse, mutect2, varscan2
- HTR1D | c.279C>T p.P93= | Silent (SNP) | VAF 67/195 reads (34%) | called by muse, mutect2, varscan2
- IRX4 | c.180G>A p.A60= | Silent (SNP) | VAF 19/111 reads (17%) | catalogued as COSV99181435; called by muse, mutect2, varscan2
- KBTBD6 | c.1161C>G p.V387= | Silent (SNP) | VAF 36/482 reads (7%) | called by muse, mutect2
- KLHL29 | c.273G>A p.A91= | Silent (SNP) | VAF 42/92 reads (46%) | catalogued as rs552154531, COSV101526528; called by muse, mutect2, varscan2
- KLHL40 | c.297G>A p.A99= | Silent (SNP) | VAF 196/296 reads (66%) | catalogued as rs555010862; called by muse, mutect2, varscan2
- LAGE3 | c.99G>A p.P33= | Silent (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2
- LATS2 | c.1170G>C p.P390= | Silent (SNP) | VAF 19/32 reads (59%) | called by muse, mutect2, varscan2
- LSS | c.1662G>A p.A554= | Silent (SNP) | VAF 42/93 reads (45%) | catalogued as rs762730550, COSV100710893; called by muse, mutect2, varscan2
- MEF2C | c.1242C>T p.H414= | Silent (SNP) | VAF 128/321 reads (40%) | catalogued as rs1403721275; called by muse, mutect2, varscan2
- MEGF8 | c.5694C>T p.A1898= (on ENST00000251268 / NM_001271938.2; = p.A1831= on NM_001410.3) | Silent (SNP) | VAF 24/100 reads (24%) | called by muse, mutect2, varscan2
- MROH2B | c.627C>T p.I209= | Silent (SNP) | VAF 57/84 reads (68%) | catalogued as rs769380827, COSV68182314; called by muse, mutect2, varscan2
- NIPAL4 | c.921G>T p.L307= | Silent (SNP) | VAF 82/464 reads (18%) | called by mutect2, varscan2
- OR3A1 | c.591C>A p.L197= | Silent (SNP) | VAF 230/378 reads (61%) | called by muse, varscan2
- OR4P4 | c.327G>A p.E109= | Silent (SNP) | VAF 28/231 reads (12%) | catalogued as COSV100111819; called by muse, mutect2, varscan2
- P2RX3 | c.741C>T p.C247= | Silent (SNP) | VAF 35/112 reads (31%) | catalogued as COSV54443518; called by muse, mutect2, varscan2
- PCDHA10 | c.1626G>A p.P542= | Silent (SNP) | VAF 262/592 reads (44%) | catalogued as COSV56489025; called by muse, mutect2, varscan2
- PKIA | c.222T>A p.S74= | Silent (SNP) | VAF 23/128 reads (18%) | catalogued as COSV61913801; called by muse, mutect2, varscan2
- POP1 | c.954G>T p.P318= | Silent (SNP) | VAF 73/464 reads (16%) | called by mutect2, varscan2
- PPFIA1 | c.1686C>A p.A562= | Silent (SNP) | VAF 8/100 reads (8%) | called by muse, mutect2
- RBM19 | c.1176C>T p.N392= | Silent (SNP) | VAF 90/380 reads (24%) | catalogued as rs145004497; called by muse, mutect2, varscan2
- RPS6KA6 | c.1362G>C p.V454= | Silent (SNP) | VAF 6/85 reads (7%) | catalogued as COSV53121116; called by muse, mutect2
- RYR2 | c.4938G>A p.E1646= | Silent (SNP) | VAF 26/130 reads (20%) | called by muse, mutect2, varscan2
- SFMBT2 | c.2175C>T p.D725= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs138925526, COSV62807670; called by muse, mutect2, varscan2
- SH3YL1 | c.981T>G p.L327= | Silent (SNP) | VAF 7/54 reads (13%) | called by muse, mutect2, varscan2
- SLC18A3 | c.1563C>T p.C521= | Silent (SNP) | VAF 54/128 reads (42%) | catalogued as COSV60329003; called by muse, mutect2, varscan2
- SLC30A10 | c.1119G>A p.A373= | Silent (SNP) | VAF 48/380 reads (13%) | catalogued as rs200960383, COSV63070885; called by muse, mutect2, varscan2
- SLC30A5 | c.480G>A p.V160= | Silent (SNP) | VAF 12/53 reads (23%) | called by muse, mutect2, varscan2
- SNPH | c.1083C>G p.P361= | Silent (SNP) | VAF 56/218 reads (26%) | catalogued as rs1300441950; called by muse, mutect2, varscan2
- TBX4 | c.582G>A p.P194= | Silent (SNP) | VAF 45/403 reads (11%) | catalogued as rs370177908; called by muse, mutect2, varscan2
- TFAP2D | c.159C>T p.T53= | Silent (SNP) | VAF 92/450 reads (20%) | called by muse, mutect2, varscan2
- TMX1 | c.636C>T p.R212= | Silent (SNP) | VAF 20/134 reads (15%) | catalogued as rs756332554; called by muse, mutect2, varscan2
- TTC9B | c.660T>C p.R220= | Silent (SNP) | VAF 8/164 reads (5%) | called by muse, mutect2
- TTLL7 | c.1029A>G p.L343= | Silent (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
- USHBP1 | c.852G>A p.Q284= | Silent (SNP) | VAF 13/100 reads (13%) | called by muse, mutect2, varscan2
- VASN | c.1890C>A p.P630= | Silent (SNP) | VAF 32/104 reads (31%) | called by mutect2, varscan2
- ZFPM2 | c.852A>G p.S284= | Silent (SNP) | VAF 16/257 reads (6%) | called by muse, mutect2
- ZNF175 | c.412C>T p.L138= | Silent (SNP) | VAF 21/115 reads (18%) | called by muse, mutect2, varscan2
- ZNF195 | c.36A>G p.E12= | Silent (SNP) | VAF 6/83 reads (7%) | called by muse, mutect2
- ZNF536 | c.2079C>T p.N693= | Silent (SNP) | VAF 20/141 reads (14%) | catalogued as rs747632104, COSV62817660; called by muse, mutect2, varscan2
- ZNF790 | c.336T>A p.L112= | Silent (SNP) | VAF 36/194 reads (19%) | called by muse, mutect2, varscan2
- ZPR1 | c.1074G>A p.L358= | Silent (SNP) | VAF 19/87 reads (22%) | called by muse, mutect2, varscan2
- ADGRL2 | c.3625+875A>G | Intron (SNP) | VAF 12/46 reads (26%) | called by muse, mutect2, varscan2
- AL033384.1 | n.190C>A | RNA (SNP) | VAF 36/109 reads (33%) | called by muse, mutect2, varscan2
- ALG2 | c.*525T>A | 3'UTR (SNP) | VAF 75/358 reads (21%) | called by muse, mutect2, varscan2
- ANKRD20A8P | n.1182A>G | RNA (SNP) | VAF 72/337 reads (21%) | called by muse, mutect2, varscan2
- AOC4P | n.502C>T | RNA (SNP) | VAF 22/385 reads (6%) | catalogued as rs190166086; called by muse, mutect2
- APOB | c.2436+96G>A | Intron (SNP) | VAF 19/107 reads (18%) | catalogued as rs772309373; called by muse, mutect2, varscan2
- ATP2A1 | c.*187G>A | 3'UTR (SNP) | VAF 58/168 reads (35%) | catalogued as rs769966625, COSV100707132; called by muse, mutect2, varscan2
- ATP8A2 | c.3184-34431C>A | Intron (SNP) | VAF 19/128 reads (15%) | called by muse, mutect2, varscan2
- BRD9 | c.401-105T>G | Intron (SNP) | VAF 66/288 reads (23%) | called by muse, mutect2, varscan2
- C8orf87 | n.388A>C | RNA (SNP) | VAF 40/232 reads (17%) | called by muse, mutect2, varscan2
- CAV1 | c.195+48G>C | Intron (SNP) | VAF 53/335 reads (16%) | called by muse, varscan2
- CEP41 | c.*3204T>C | 3'UTR (SNP) | VAF 109/281 reads (39%) | called by muse, mutect2, varscan2
- CFAP54 | c.4547+803_4547+804insC | Intron (INS) | VAF 14/107 reads (13%) | called by mutect2, pindel, varscan2
- COG6 | c.*601G>C | 3'UTR (SNP) | VAF 17/338 reads (5%) | called by muse, mutect2
- CSMD3 | c.178+59893G>C | Intron (SNP) | VAF 76/564 reads (13%) | called by muse, mutect2
- DHFR | c.-41C>T | 5'UTR (SNP) | VAF 34/167 reads (20%) | catalogued as rs752021512; called by muse, mutect2, varscan2
- ELN | chr7:74068726 C>A | 3'Flank (SNP) | VAF 13/142 reads (9%) | called by muse, mutect2
- EXD1 | c.28+3985G>A | Intron (SNP) | VAF 8/43 reads (19%) | catalogued as rs781573282; called by muse, mutect2, varscan2
- FASTKD2 | c.1899-18G>T | Intron (SNP) | VAF 30/214 reads (14%) | called by mutect2, varscan2
- FOXP2 | c.*259_*260insC | 3'UTR (INS) | VAF 34/136 reads (25%) | called by pindel, varscan2
- HERC2P3 | n.447C>T | RNA (SNP) | VAF 58/230 reads (25%) | called by muse, mutect2, varscan2
- KIAA1328 | chr18:37229601 C>T | 3'Flank (SNP) | VAF 7/63 reads (11%) | catalogued as rs771000552; called by muse, mutect2, varscan2
- LINC01619 | n.511A>G | RNA (SNP) | VAF 16/128 reads (13%) | catalogued as rs533717343; called by muse, mutect2, varscan2
- MIR29A | n.25G>C | RNA (SNP) | VAF 16/164 reads (10%) | called by muse, mutect2
- MIR450A2 | n.20T>A | RNA (SNP) | VAF 24/127 reads (19%) | called by muse, mutect2, varscan2
- NBPF11 | c.-548-3010C>T | Intron (SNP) | VAF 15/390 reads (4%) | catalogued as rs1455538565; called by muse, mutect2
- NOX5 | c.-14G>C | 5'UTR (SNP) | VAF 20/84 reads (24%) | called by muse, mutect2, varscan2
- PABPC1P2 | n.1175C>T | RNA (SNP) | VAF 62/436 reads (14%) | called by muse, mutect2, varscan2
- PDZD7 | c.720-29C>T | Intron (SNP) | VAF 72/336 reads (21%) | called by muse, mutect2, varscan2
- PKP2 | c.1689-34G>C | Intron (SNP) | VAF 14/160 reads (9%) | called by muse, mutect2
- PPP1R13B | c.*533G>T | 3'UTR (SNP) | VAF 46/212 reads (22%) | called by muse, mutect2, varscan2
- PRKG1 | c.935+18990A>G | Intron (SNP) | VAF 31/175 reads (18%) | called by muse, mutect2, varscan2
- SSTR5-AS1 | n.730G>A | RNA (SNP) | VAF 8/22 reads (36%) | catalogued as rs1383146817; called by muse, mutect2, varscan2
- SVOPL | c.*19C>G | 3'UTR (SNP) | VAF 6/150 reads (4%) | called by muse, mutect2
- TFAP2E | c.562+2411G>A | Intron (SNP) | VAF 79/198 reads (40%) | catalogued as COSV64697366; called by muse, mutect2, varscan2
- TGFBR3 | c.*2702T>G | 3'UTR (SNP) | VAF 43/237 reads (18%) | called by muse, mutect2, varscan2
- TRIM6 | c.-68+684A>C | Intron (SNP) | VAF 12/150 reads (8%) | called by muse, mutect2
- TRPA1 | c.1645-30A>C | Intron (SNP) | VAF 42/434 reads (10%) | called by muse, mutect2
- TSC22D1 | c.2912+33285G>C | Intron (SNP) | VAF 27/101 reads (27%) | called by muse, mutect2, varscan2
- TSHZ2 | c.*2056G>C | 3'UTR (SNP) | VAF 15/187 reads (8%) | called by muse, mutect2
- URGCP | c.42-13G>A | Intron (SNP) | VAF 17/119 reads (14%) | called by muse, mutect2, varscan2
- VCP | c.946-25C>A | Intron (SNP) | VAF 152/690 reads (22%) | called by muse, mutect2
- VCP | c.946-27T>A | Intron (SNP) | VAF 150/688 reads (22%) | called by muse, mutect2
- ZNF277 | c.801+56T>G | Intron (SNP) | VAF 27/201 reads (13%) | called by muse, mutect2, varscan2
- ZNF81 | c.181+60A>C | Intron (SNP) | VAF 36/143 reads (25%) | called by muse, mutect2, varscan2
